Surgical pathology report (de-identified scan), TCGA case TCGA-06-A6S1, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-A6S1-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3

Glioblastoma multiforme
C60F (9440/3)
Site Brain NOS C71.9
path
Brain, frontal lobe C71.1
7/24/13

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: F Accnt: Reported:
Physician(s):
Phy Location:

Clinical History

woman has had bowel and urinary incontinence and leg weakness with L5-S1 spine degeneration for about six to eight months. the patient has experienced headache and expressive aphasia.

On imaging, there are multifocal lesions, some interconnected, in both cerebral hemispheres, more numerous on the right side. The masses are irregularly enhancing.

Operative Diagnoses

Brain tumor

Operation / Specimen

- A: Brain, right frontal tumor, excision biopsy
B: Right frontal tumor, excision biopsy

Pathologic Diagnosis

A, B. Brain, right frontal, craniotomy:

1. Glioblastoma, WHO grade 4
2. Negative immunostain for mutant IDH1-R132H protein
3. Negative for codeletion of chromosomal arms 1p and 19q
4. Ki-67/ MIB-1 proliferation index: up to 23%

***Electronically Signed Out By
Staff Pathologist***

Senior

Senior Staff Pathologist

Procedures/Addenda

PCR for EGFR variant III mutation

Date Ordered: Date Reported:

Interpretation

POSITIVE - EGFRvIII mutation is detected

Results-Comments

Surgical Pathology

Page 2 of 4

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block (A3)

H and E slide was examined and no microdissection was needed.

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma.

Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR

[page 2 of 4]
tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.
FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from paraffin tissue block (A3)

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

Surgical Pathology

Page 3 of 4

Senior Staff Pathologist

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered:

Date Reported:

Interpretation

POSITIVE: Allelic loss on chromosome arm 19q is detected.

[page 3 of 4]
Allelic loss on chromosome arm 1p is not detected

Informative loci are: D1S548, D1S1592, D19S412, D19S606, D19S1182

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A3). DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A. Brain, right frontal tumor, excision biopsy:

1. Sparsely cellular, few gemistocyte astrocytes. No lymphoma or inflammation. Touch preparation smears

performed at and results reported to the Physician of Record.

2. Diffuse proliferation of gemistocyte-like astrocytes (C/W diffuse astrocytic neoplasm, high grade, R/O other. No

lymphoma). Frozen section performed at . and results reported to the Physician of Record.

Senior

Staff Pathologist

Gross Description

Surgical Pathology

Page 4 of 4

A. "Brain, right frontal tumor," received fresh, one fragment of cerebral tissue, 2.3 x 2.3 x 1.3 cm. Semi firm, pasty, poor cortical-white matter interphase, creamy-white. Serially sectioned. Half of specimen submitted, A1-A4, frozen tissue A5.

B. "Right frontal tumor," excision biopsy: CONTAINER LABEL: right frontal tumor.

[page 4 of 4]
FIXATIVE: Formalin. NO. PIECES: several gray tan fragments. SIZE/VOL: 2.2 x 1.8 x 0.8 cm., 1.25 grams
CASSETTES: 1, 2 NS.

ICD-9(s): 323.9 323.9

Billing Fee Code(s): A:

B:

EGFRvIII:

LOH 1p19q:

MGMT:

Histo Data

Part A: Brain, right frontal tumor, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

TPS H&E x 1 1

H&E x 1 2

x 1 3 Run IDH1, please

EGFR vIII-curis x 1 3

H&E x 1 3

LOH-curis x 1 3

LOH-curis x 1 3

MGMT-curis x 1 3

MIB1-DA x 1 3

H&E x 1 4

FS H&E x 1 5

H&E x 1 5

Part B: Right frontal tumor, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

H&E x 1 2

Agonosis Discrepancy		✓
HPA Discrepancy		✓

Source: NCI Genomic Data Commons file fca1aed2-818f-4ced-915a-3a58af03855e (TCGA-06-A6S1.0BAB6F0A-77A8-4D16-B4E6-1AC173521399.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).